Somatic mutation profile of tumor specimen C3N-01536-03 (aliquot CPT0096890009) from CPTAC case C3N-01536, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.2 years (23,816 days).
Specimen C3N-01536-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99e6d5e9-919b-4b53-9297-82ad497fde0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01536-31 (Blood Derived Normal), aliquot CPT0096910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab2f4600-0343-4e1f-9396-f94242d77bd3

The open-access MAF lists 72 somatic variants for this specimen: 51 protein-altering or splice-affecting, 7 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 7, Frame Shift Del 6, RNA 5, Nonsense Mutation 5, Intron 4, 3'UTR 3, Splice Region 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH13 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs750850181; called by muse, mutect2, varscan2
- DNAH8 | c.12502C>G p.Q4168E | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.04); catalogued as COSV59448079; called by muse, mutect2, varscan2
- HOOK2 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 45/179 reads (25%) | catalogued as rs1307170050; called by muse, mutect2, varscan2
- KMT2D | c.9583C>A p.L3195M | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV56499883; called by muse, mutect2, varscan2
- LILRA1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1361562599; called by muse, varscan2
- MASTL | c.2468G>C p.R823T (on ENST00000375940 / NM_001372029.1; = p.R822T on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751976926, COSV100668874; called by muse, mutect2, varscan2
- NCOR2 | c.6190G>A p.D2064N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs775031589; called by muse, mutect2, varscan2
- PMFBP1 | c.2948G>A p.G983D (on ENST00000537465; = p.G978D on NM_031293.3) | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as rs762853798; called by muse, mutect2, varscan2
- SIGLEC10 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs372246670; called by muse, mutect2, varscan2
- TLR6 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs772411747; called by muse, mutect2, varscan2
- VHL | c.433_434dup p.Q145Hfs*15 | Frame Shift Ins (INS) | VAF 125/320 reads (39%) | catalogued as CI1510664; called by mutect2, pindel, varscan2
- ZNF213 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs765247881; called by muse, mutect2, varscan2
- AADAC | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK2 | c.14467C>A p.P4823T | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AP1M1 | c.656T>A p.L219H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AURKC | c.880C>T p.Q294* (on ENST00000302804 / NM_001015878.2; = p.Q260* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 78/268 reads (29%) | called by muse, mutect2, varscan2
- BRD1 | c.2705C>T p.A902V (on ENST00000216267 / NM_001349940.1; = p.A1033V on NM_001304808.3) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFAP54 | c.2889+1G>T p.X963_splice | Splice Site (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- CNNM1 | c.837del p.T280Pfs*82 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- DNAH9 | c.12490-2del p.X4164_splice | Splice Site (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- DPP9 | c.554C>G p.S185* (on ENST00000598800; = p.S214* on NM_139159.5) | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- EPM2AIP1 | c.1510_1515del p.R504_V505del | In Frame Del (DEL) | VAF 30/145 reads (21%) | called by pindel, varscan2
- ETV3L | c.319_322del p.L107Ifs*19 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- FCHO1 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GATM | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GLIS3 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- HMGXB3 | c.807del p.Y269* (on ENST00000613459; = p.Y23* on NM_014983.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 55/215 reads (26%) | called by mutect2, pindel, varscan2
- IL17RB | c.1379T>A p.L460H | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQCN | c.1436_1440del p.T479Ifs*69 | Frame Shift Del (DEL) | VAF 78/308 reads (25%) | called by mutect2, pindel, varscan2
- JPH2 | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- KCNT2 | c.1064A>G p.Q355R | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KDM5C | c.4196_4211del p.L1399Wfs*8 | Frame Shift Del (DEL) | VAF 93/182 reads (51%) | called by mutect2, pindel, varscan2
- LAMP1 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- LMBR1 | c.426A>T p.G142= | Splice Region (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- MKRN1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MMP19 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- MORC2 | c.2807C>G p.A936G (on ENST00000397641 / NM_001303256.3; = p.A874G on NM_014941.3) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- NEK8 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCED1B | c.89dup p.Y30* | Nonsense Mutation (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- PTPRF | c.4559C>A p.P1520H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- QRICH2 | c.3422A>G p.K1141R | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SCO2 | c.113del p.L38Cfs*25 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | called by mutect2, pindel, varscan2
- SLC25A25 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORBS2 | c.2492G>C p.G831A | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2
- SOX18 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRIP1 | c.327G>T p.V109= | Splice Region (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- TH | c.565C>T p.P189S (on ENST00000381178 / NM_199292.3; = p.P158S on NM_000360.4) | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2
- TRPM3 | c.4181T>C p.V1394A (on ENST00000357533 / NM_001366142.2; = p.V1249A on NM_020952.6) | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.4789C>G p.L1597V | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUBA3C | c.1166C>A p.A389D | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ZNF341 | c.2497C>A p.L833M (on ENST00000375200 / NM_001282935.1; = p.L826M on NM_032819.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, varscan2
- ABCA1 | c.2859C>G p.T953= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as COSV66069310; called by muse, mutect2, varscan2
- BCL11A | c.1221T>G p.G407= (on ENST00000335712 / NM_001365609.1; = p.G441= on NM_018014.4) | Silent (SNP) | VAF 92/339 reads (27%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.426G>A p.R142= | Silent (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.1230C>T p.V410= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- IGSF9B | c.3096A>G p.T1032= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as rs536634479; called by muse, mutect2, varscan2
- RGS12 | c.1707C>T p.C569= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as rs1034425271, COSV100375895; called by muse, mutect2, varscan2
- WDR33 | c.3102G>A p.G1034= | Silent (SNP) | VAF 80/338 reads (24%) | called by muse, mutect2, varscan2
- ADAM6 | n.1079G>T | RNA (SNP) | VAF 81/298 reads (27%) | catalogued as rs1555410912; called by muse, mutect2, varscan2
- AGAP12P | n.194C>T | RNA (SNP) | VAF 99/514 reads (19%) | catalogued as rs782252177; called by muse, mutect2, varscan2
- AL137230.1 | n.502+1678C>A | Intron (SNP) | VAF 21/83 reads (25%) | called by muse, varscan2
- ALMS1P1 | n.852C>T | RNA (SNP) | VAF 66/241 reads (27%) | catalogued as rs769744079; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504309 T>C | 5'Flank (SNP) | VAF 17/54 reads (31%) | called by mutect2, varscan2
- C5orf60 | n.1744T>A | RNA (SNP) | VAF 89/370 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.4386C>T | RNA (SNP) | VAF 35/130 reads (27%) | catalogued as COSV61777301; called by muse, mutect2, varscan2
- GJA9 | c.-155A>G | 5'UTR (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46525C>T | Intron (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- MTSS2 | c.*2353A>G | 3'UTR (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1024+23_1024+24del | Intron (DEL) | VAF 52/210 reads (25%) | called by mutect2, pindel, varscan2
- SCTR | c.1141-12T>G | Intron (SNP) | VAF 43/151 reads (28%) | called by muse, mutect2, varscan2
- SSR3 | c.*3C>T | 3'UTR (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- ZNF395 | c.*52del | 3'UTR (DEL) | VAF 60/212 reads (28%) | called by mutect2, pindel, varscan2
